Somatic mutation profile of tumor specimen TCGA-B8-A8YJ-01A (aliquot TCGA-B8-A8YJ-01A-13D-A38X-10) from TCGA case TCGA-B8-A8YJ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.2 years (21,994 days).
Specimen TCGA-B8-A8YJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27aac0cd-d4b1-43fa-9bd9-68a704b0d64f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A8YJ-10A (Blood Derived Normal), aliquot TCGA-B8-A8YJ-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45fcc6f8-a23c-4daa-a55f-bd05fc6715dc

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP1 | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100027947; called by muse, mutect2
- ANKLE2 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100514115; called by muse, mutect2
- ATP13A1 | c.1007G>T p.C336F | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99366150; called by muse, mutect2
- CADPS | c.3700G>A p.V1234M | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51866938; called by muse, mutect2
- CTSA | c.631T>G p.Y211D | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99509869; called by muse, mutect2
- DSCAML1 | c.3028G>A p.V1010M (on ENST00000321322; = p.V950M on NM_020693.4) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100355980; called by muse, mutect2
- ELAVL4 | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as COSV100836741; called by muse, mutect2
- EVI5 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288944951, COSV100789681; called by muse, mutect2
- HMGN5 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.092); catalogued as COSV100814910; called by muse, mutect2
- IQUB | c.1709A>G p.H570R | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100227120; called by muse, mutect2
- RAB11FIP3 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV99240288; called by muse, mutect2
- RPRD1B | c.291T>A p.D97E | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV100987233; called by muse, mutect2
- SETD2 | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.398); catalogued as COSV100339002; called by muse, mutect2
- SGO2 | c.2820T>G p.D940E | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV100764678; called by muse, mutect2, varscan2
- SPATA31D1 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV100782789, COSV100782827; called by muse, mutect2
- TEX101 | c.397A>T p.T133S (on ENST00000598265 / NM_001130011.3; = p.T151S on NM_031451.4) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99494820; called by muse, mutect2
- UBE2A | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV100660506; called by muse, mutect2
- ZNF620 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100094063, COSV58820793; called by muse, mutect2
- SLC49A4 | c.47_61del p.G16_P21delinsA | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- TPTE | c.1522C>A p.L508I (on ENST00000618007 / NM_199261.4; = p.L490I on NM_199259.4) | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CACNA1S | c.1818C>T p.S606= | Silent (SNP) | VAF 20/276 reads (7%) | catalogued as rs34025878; called by muse, mutect2
- HNRNPAB | c.400A>C p.R134= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV100359384; called by muse, mutect2
- KAT6B | c.4815C>A p.S1605= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs762105075, COSV99768096; called by muse, mutect2
- SLIRP | c.*326T>A | 3'UTR (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99834344; called by muse, mutect2
